Somatic mutation profile of tumor specimen TCGA-EM-A2CM-01A (aliquot TCGA-EM-A2CM-01A-11D-A17V-08) from TCGA case TCGA-EM-A2CM, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 62.2 years (22,726 days).
Specimen TCGA-EM-A2CM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adcbdd92-8a3d-472c-b401-2f1486e89543.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A2CM-10A (Blood Derived Normal), aliquot TCGA-EM-A2CM-10A-01D-A17V-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ccdb2a9d-f5ae-4eba-8345-ff18c1c51cd7

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 49/101 reads (49%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs121913233, COSV54236656, COSV54236691, COSV54238654; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AGAP6 | c.1946G>A p.C649Y (on ENST00000374056 / NM_001365867.1; = p.C672Y on NM_001077665.2) | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100929092; called by mutect2, varscan2
- AL592490.1 | c.1364C>A p.T455N | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV101308215; called by muse, mutect2, varscan2
- ANK1 | c.4117G>A p.E1373K | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as rs745689377, COSV55888705; called by muse, mutect2, varscan2
- BLMH | c.1013T>A p.L338H | Missense Mutation (SNP) | VAF 142/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV99913151; called by muse, mutect2, varscan2
- COBL | c.2221A>G p.S741G | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV99472802; called by muse, mutect2, varscan2
- ECHDC2 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 43/83 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as rs1356397403, COSV100597638; called by muse, mutect2, varscan2
- IRAK3 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 71/159 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs199538395; called by muse, mutect2, varscan2
- IRS1 | c.1659G>T p.E553D | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV100524608; called by muse, mutect2, varscan2
- LARP4B | c.1597A>G p.S533G | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.242); catalogued as COSV100295384, COSV100295454; called by muse, mutect2, varscan2
- MTSS2 | c.1532T>G p.F511C | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV99851875; called by muse, mutect2, varscan2
- RNF19B | c.695G>A p.G232D | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99331489; called by muse, mutect2, varscan2
- RORB | c.524C>T p.S175F (on ENST00000396204 / NM_001365023.1; = p.S164F on NM_006914.4) | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100974361; called by muse, mutect2, varscan2
- SIGLEC12 | c.208G>C p.V70L | Missense Mutation (SNP) | VAF 58/121 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs541963042, COSV99389397; called by muse, mutect2, varscan2
- TUT1 | c.1180C>G p.R394G | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.314); catalogued as COSV99545352; called by muse, mutect2, varscan2
- ZBTB2 | c.1382A>G p.N461S | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.165); catalogued as rs766015279, COSV57311629; called by muse, mutect2, varscan2
- ZNF490 | c.476G>T p.S159I | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100267376; called by muse, mutect2, varscan2
- RBM10 | c.2390_2411del p.S797* | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- TG | c.2460dup p.I821Yfs*6 | Frame Shift Ins (INS) | VAF 31/76 reads (41%) | called by mutect2, pindel, varscan2
- AKAP10 | c.1635G>T p.A545= | Silent (SNP) | VAF 18/61 reads (30%) | catalogued as COSV99855467; called by muse, mutect2, varscan2
- CAMK2A | c.48C>T p.F16= | Silent (SNP) | VAF 47/92 reads (51%) | catalogued as rs753516638, COSV62247051, COSV62247885; called by muse, mutect2, varscan2
- H4C12 | c.21C>T p.G7= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as rs530871581, COSV100694796; called by mutect2, varscan2
- OTP | c.348C>T p.L116= | Silent (SNP) | VAF 102/208 reads (49%) | catalogued as COSV100119826; called by muse, mutect2, varscan2
- SEC24D | c.948A>G p.T316= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99756173; called by muse, mutect2, varscan2
- UBASH3B | c.909C>T p.T303= | Silent (SNP) | VAF 33/240 reads (14%) | catalogued as rs766919387, COSV52502366; called by muse, mutect2, varscan2
- ZNF227 | c.987C>T p.C329= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs372984825, COSV100480416; called by muse, mutect2, varscan2
